CCDI case PBCARC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/f1a11c98-7d75-42f9-8a2f-51782f28b577

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 16.1 years (5,882 days).

Biospecimens (2 samples)
- Sample 0DML9O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMLA3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
